Somatic mutation profile of tumor specimen TCGA-G2-A2EC-01A (aliquot TCGA-G2-A2EC-01A-11D-A17V-08) from TCGA case TCGA-G2-A2EC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 58.1 years (21,215 days).
Specimen TCGA-G2-A2EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2edd198-7eaa-476b-bcda-fdb8d5016151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2EC-10A (Blood Derived Normal), aliquot TCGA-G2-A2EC-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93321e72-7ce3-4c03-9319-2197745f839b

The open-access MAF lists 193 somatic variants for this specimen: 140 protein-altering or splice-affecting, 46 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 46, Nonsense Mutation 12, Frame Shift Del 4, Intron 3, Splice Site 2, In Frame Del 2, RNA 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61222386; called by muse, mutect2, varscan2
- ACTL6A | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV66999061; called by muse, mutect2, varscan2
- ADAMTS12 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV61265014; called by muse, mutect2, varscan2
- AIP | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs775850708, COSV54160906; called by muse, mutect2, varscan2
- AMIGO3 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV57537389, COSV57538940; called by muse, mutect2, varscan2
- ANAPC7 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV71443849; called by muse, mutect2
- ANGPTL6 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981433687, COSV53462609; called by muse, mutect2, varscan2
- ANKRD1 | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1199432486, COSV65467709; called by muse, mutect2, varscan2
- ANKRD46 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV59514714; called by muse, mutect2, varscan2
- ANO4 | c.2513G>C p.R838P (on ENST00000392977 / NM_001286615.2; = p.R803P on NM_178826.4) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV54596564, COSV54598541; called by muse, mutect2, varscan2
- AP2B1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV52000121; called by muse, mutect2, varscan2
- ASL | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1405344068, COSV59188543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN7L2 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63992403; called by muse, mutect2, varscan2
- BCAS3 | c.1363A>G p.M455V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as rs751188935, COSV66775355; called by muse, mutect2, varscan2
- BMF | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as rs760034128, COSV55018649; called by muse, mutect2, varscan2
- C19orf44 | c.976T>G p.L326V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.067); catalogued as COSV55612543; called by muse, mutect2, varscan2
- C3orf62 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100542921, COSV57985901; called by muse, mutect2, varscan2
- CDK12 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV71001022; called by muse, mutect2, varscan2
- CFAP94 | c.532C>G p.L178V (on ENST00000320267 / NM_001352064.2; = p.L184V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.084); catalogued as COSV57232785; called by muse, mutect2, varscan2
- CFH | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV66409336; called by muse, mutect2
- CFP | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55950478; called by muse, mutect2, varscan2
- CHD4 | c.4366G>C p.E1456Q (on ENST00000357008 / NM_001363606.2; = p.E1469Q on NM_001273.5) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58902761; called by muse, mutect2, varscan2
- CHPF2 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50391590; called by muse, mutect2, varscan2
- CLIP2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56280311; called by mutect2, varscan2
- COLEC12 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68371122; called by muse, mutect2, varscan2
- CR1L | c.127T>A p.F43I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54327116; called by muse, mutect2, varscan2
- CRAT | c.288C>G p.N96K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747784734, COSV58877357; called by muse, mutect2, varscan2
- CSMD3 | c.6346T>C p.S2116P (on ENST00000297405 / NM_001363185.1; = p.S2012P on NM_052900.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV52138934, COSV52202399; called by muse, mutect2, varscan2
- CTNND2 | c.2273G>T p.S758I | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58894533; called by muse, mutect2, varscan2
- CUL1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.816); catalogued as COSV57389316; called by muse, mutect2
- CYFIP2 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.953); catalogued as rs775941668, COSV59040772; called by mutect2, varscan2
- DEPDC5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV56699651; called by muse, mutect2, varscan2
- DIAPH1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53881157, COSV53883442; called by muse, mutect2, varscan2
- DIDO1 | c.5893C>T p.Q1965* | Nonsense Mutation (SNP) | VAF 53/272 reads (19%) | catalogued as COSV56633363; called by muse, mutect2, varscan2
- DIDO1 | c.5426C>A p.S1809Y | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV56624951, COSV56634305; called by muse, varscan2
- DIDO1 | c.4862C>T p.S1621L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs745359035, COSV99826377; called by muse, mutect2, varscan2
- DNAH1 | c.5459G>A p.G1820D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV70229958; called by muse, varscan2
- DUOX2 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375229316; called by muse, mutect2, varscan2
- EIF2AK4 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV55469333; called by muse, mutect2, varscan2
- EMILIN3 | c.2162G>T p.R721I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60034905; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1118C>G p.S373* | Nonsense Mutation (SNP) | VAF 60/192 reads (31%) | catalogued as rs765401720, COSV51620594, COSV99212541; called by muse, varscan2
- EPOR | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs767356681, COSV55800567; called by muse, mutect2, varscan2
- ESRP2 | c.2053G>C p.A685P (on ENST00000565858 / NM_001365264.1; = p.A675P on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV52173897; called by muse, mutect2, varscan2
- FAHD2B | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV55631190; called by muse, mutect2, varscan2
- FBXL20 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV52899833; called by muse, mutect2, varscan2
- FER | c.1533+1G>A p.X511_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as rs766775276, COSV55293169; called by muse, mutect2, varscan2
- FMN1 | c.3604G>A p.D1202N (on ENST00000616417 / NM_001277313.2; = p.D979N on NM_001103184.4) | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374358070; called by muse, mutect2, varscan2
- FREM2 | c.1705C>A p.L569M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54840471; called by muse, mutect2, varscan2
- FSIP2 | c.19543G>C p.E6515Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV58088635; called by muse, mutect2, varscan2
- FZD9 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs559231844, COSV60669525; called by muse, mutect2, varscan2
- GALNT15 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60217644; called by muse, mutect2, varscan2
- GOT1L1 | c.1178A>T p.E393V | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV56875971; called by muse, mutect2, varscan2
- GPRIN3 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV60885218; called by muse, varscan2
- HAUS4 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52827524; called by muse, mutect2
- ICA1L | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100841768, COSV64173631; called by muse, mutect2, varscan2
- ITGA2B | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52232958; called by muse, mutect2
- ITGB3 | c.2317T>C p.Y773H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV71384204; called by muse, mutect2, varscan2
- KIAA0100 | c.6301G>A p.D2101N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382397; called by muse, mutect2, varscan2
- KIAA0100 | c.5805G>C p.Q1935H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56382407; called by muse, mutect2, varscan2
- KITLG | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57202186, COSV99933183; called by muse, mutect2, varscan2
- LAMA3 | c.2002G>C p.D668H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58070235; called by muse, mutect2, varscan2
- LAMA3 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58070242; called by muse, mutect2, varscan2
- LEF1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54468270; called by muse, mutect2, varscan2
- LEF1 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV54468302; called by muse, mutect2, varscan2
- LRP1B | c.7960C>A p.L2654M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.929); catalogued as COSV67230203; called by muse, mutect2, varscan2
- MGA | c.6635C>G p.S2212* (on ENST00000219905 / NM_001164273.1; = p.S2003* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as COSV54964750; called by muse, mutect2, varscan2
- MIOS | c.85C>G p.H29D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV60768878; called by muse, mutect2, varscan2
- MOGAT2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52219974; called by muse, mutect2, varscan2
- NAP1L4 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65880839; called by muse, mutect2, varscan2
- NFKB2 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51872351; called by muse, mutect2
- NHLRC1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV61481576; called by muse, mutect2, varscan2
- NKTR | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as COSV51772444; called by muse, mutect2, varscan2
- NOTCH2 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV56698833; called by muse, mutect2, varscan2
- NRP1 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs760298219, COSV55168842; called by muse, mutect2, varscan2
- NSMCE1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63863757, COSV63864379; called by muse, mutect2, varscan2
- NUP85 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); catalogued as COSV55457093; called by muse, mutect2, varscan2
- OR5D18 | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV61736380, COSV61737416; called by muse, mutect2, varscan2
- PAN2 | c.933del p.C312Vfs*15 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as COSV57754267; called by mutect2, pindel, varscan2
- PANX1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57134077, COSV57134746; called by muse, mutect2, varscan2
- PCDHB1 | c.1577A>G p.Q526R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.145); catalogued as COSV60631392; called by muse, mutect2, varscan2
- PCDHGA11 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV53963565; called by muse, mutect2, varscan2
- PDE6H | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56761031; called by muse, mutect2, varscan2
- PHLDB1 | c.3441G>C p.K1147N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV61879243; called by muse, mutect2, varscan2
- PKHD1 | c.6917C>T p.S2306F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV61879745; called by muse, mutect2, varscan2
- PKIG | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV63068979; called by muse, mutect2, varscan2
- PLCH1 | c.4298C>G p.S1433C (on ENST00000340059 / NM_001130960.2; = p.S1425C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV58199969; called by muse, mutect2, varscan2
- POLQ | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV51756473; called by muse, varscan2
- PRORP | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV51619144; called by muse, mutect2, varscan2
- PTCHD1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs727504113, COSV65059472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PURG | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53299345; called by muse, mutect2, varscan2
- RARS1 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV51563987; called by muse, mutect2, varscan2
- RBBP6 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60505736; called by muse, mutect2, varscan2
- RPP25L | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.333); catalogued as COSV52407729; called by muse, mutect2, varscan2
- RTP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.708); catalogued as rs747814477; called by muse, mutect2
- SCARA3 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV57270422; called by muse, mutect2, varscan2
- SCG2 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.83); catalogued as rs137998511, COSV100544911, COSV59540470; called by muse, mutect2, varscan2
- SHANK2 | c.5116C>T p.R1706C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs370486550; called by muse, mutect2
- SLC12A3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199745548, CM1510317; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A19 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765501634, CM085709, COSV58671847; called by muse, mutect2, varscan2
- SLCO1B1 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1317719180, COSV57012142; called by muse, mutect2, varscan2
- SNX21 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54169863; called by muse, mutect2, varscan2
- SPATA2 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56867593; called by muse, mutect2, varscan2
- STIP1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs1303540859, COSV54180602; called by muse, mutect2, varscan2
- STON2 | c.1477G>A p.E493K (on ENST00000649389 / NM_001366849.2; = p.E436K on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50846036; called by muse, varscan2
- TAOK2 | c.3200G>A p.G1067D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as rs972217949, COSV54229387, COSV54230406; called by muse, mutect2, varscan2
- TECPR2 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV63971144; called by muse, mutect2, varscan2
- TMC3 | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as rs1182638725, COSV63923438; called by muse, mutect2, varscan2
- TNXB | c.11144C>A p.S3715Y (on ENST00000647633; = p.S3468Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747559127, COSV100926452; called by muse, mutect2
- TP53I13 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as COSV56195592, COSV99838484; called by muse, mutect2, varscan2
- TRERF1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61672919; called by muse, mutect2, varscan2
- TTN | c.86594G>T p.S28865I (on ENST00000591111; = p.S21441I on NM_003319.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60062307; called by muse, mutect2, varscan2
- TTN | c.51452T>A p.I17151K (on ENST00000591111; = p.I9727K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | PolyPhen probably damaging (0.961); catalogued as COSV60113464; called by muse, mutect2, varscan2
- UBE2L6 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.976); catalogued as COSV54703118, COSV54703506; called by muse, mutect2, varscan2
- UBOX5 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762767779, COSV53905449; called by muse, mutect2, varscan2
- USP24 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV53769459; called by muse, mutect2
- WDR90 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.021); catalogued as COSV53470965; called by muse, mutect2, varscan2
- ZBED9 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101509088, COSV101509447, COSV71729472; called by muse, mutect2, varscan2
- ZC3H4 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV53413550; called by muse, mutect2, varscan2
- ZNF121 | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57551769; called by muse, mutect2, varscan2
- ZNF208 | c.3086A>G p.Y1029C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs754583633, COSV68107424; called by muse, mutect2, varscan2
- ZNF266 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as COSV63222321; called by muse, mutect2, varscan2
- ZSCAN1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs762756499, COSV56601700, COSV99991703; called by muse, mutect2
- ZSWIM2 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54576145; called by muse, mutect2, varscan2
- AATF | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GINS3 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); called by muse, mutect2
- HTR2B | c.576_591del p.I192Mfs*13 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- KPNB1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LRRC37A3 | c.2979-1G>C p.X993_splice | Splice Site (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- MRNIP | c.723_752del p.H241_L250del | In Frame Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel
- NCOA1 | c.1769C>G p.S590* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- OR8B4 | c.904_914del p.K302Efs*18 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- SMC1A | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- SPTAN1 | c.3838_3839del p.R1280Gfs*7 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by pindel, varscan2
- STRC | c.4271G>A p.W1424* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- SUPT6H | c.1367C>G p.S456* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- TFG | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- TMEM204 | c.589_606del p.C197_V202del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- TRGV2 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TXNIP | c.98dup p.E34Gfs*4 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- ABL1 | c.39A>G p.R13= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV64903199; called by muse, mutect2, varscan2
- ACTL6A | c.504G>A p.L168= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV66999057; called by muse, mutect2, varscan2
- ADAMTS14 | c.1545C>T p.F515= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV100941324, COSV64602821; called by muse, mutect2, varscan2
- ANKFN1 | c.1173G>A p.L391= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs919491346, COSV59449441; called by muse, mutect2, varscan2
- ATXN7L2 | c.387G>C p.V129= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV63992408; called by muse, mutect2, varscan2
- BACH2 | c.2280C>T p.C760= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs368652670; called by muse, mutect2, varscan2
- C8A | c.999C>T p.F333= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV63484654; called by muse, mutect2, varscan2
- CACNB1 | c.486C>T p.P162= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs749339991, COSV59999072; called by muse, mutect2, varscan2
- CAPN9 | c.658C>T p.L220= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55234417; called by muse, varscan2
- CBLB | c.960G>C p.L320= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV51428657; called by muse, mutect2, varscan2
- CLIP2 | c.2790G>C p.L930= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs782078080, COSV56280326; called by muse, mutect2, varscan2
- DIDO1 | c.4330C>T p.L1444= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV56624961; called by muse, mutect2, varscan2
- DNAH10 | c.6642C>T p.Y2214= (on ENST00000409039; = p.Y2153= on NM_207437.3) | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs753490414, COSV68995135; called by muse, mutect2, varscan2
- DOCK3 | c.2856C>T p.L952= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99814855; called by muse, mutect2
- GLI3 | c.2763C>T p.L921= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1486073428, COSV67889438; called by muse, mutect2, varscan2
- HSD3B7 | c.108C>T p.L36= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs377494419; called by muse, mutect2
- KCNH1 | c.687C>T p.F229= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55085444; called by muse, mutect2, varscan2
- LRFN2 | c.1659C>T p.L553= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1343428652, COSV57828445; called by muse, mutect2, varscan2
- MAP4K1 | c.270C>T p.C90= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV50264189; called by muse, mutect2, varscan2
- MRPL10 | c.666C>G p.L222= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV50109565; called by muse, mutect2, varscan2
- MTHFR | c.1443C>T p.T481= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV57172875; called by muse, mutect2, varscan2
- MYBPC1 | c.2310T>C p.N770= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV62253689; called by muse, mutect2, varscan2
- MYLK | c.5095C>T p.L1699= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60612214; called by muse, varscan2
- MYOM1 | c.3045C>T p.N1015= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1167280865, COSV55292525; called by muse, mutect2, varscan2
- NPBWR1 | c.906C>T p.L302= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58696461; called by muse, mutect2, varscan2
- OR1N2 | c.606C>A p.I202= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs1197924595, COSV65460782, COSV65460829; called by muse, mutect2, varscan2
- PANX3 | c.186T>C p.S62= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV52512421; called by muse, mutect2, varscan2
- PARD6A | c.958C>T p.L320= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54668199; called by muse, mutect2, varscan2
- PLCH1 | c.4803G>A p.K1601= (on ENST00000340059 / NM_001130960.2; = p.K1593= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs1301074872, COSV58199944; called by muse, mutect2, varscan2
- POFUT1 | c.453C>T p.F151= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV65260073, COSV65260467; called by muse, varscan2
- RBM10 | c.2028C>A p.I676= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV61309653; called by muse, mutect2, varscan2
- RER1 | c.33C>T p.V11= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60383697; called by muse, mutect2, varscan2
- RICTOR | c.2526G>A p.L842= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV57123423; called by muse, mutect2, varscan2
- RSKR | c.321G>A p.L107= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV56382346; called by muse, mutect2, varscan2
- SGPP2 | c.1008C>G p.L336= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1355229259, COSV58329469; called by muse, mutect2, varscan2
- SH3PXD2B | c.1083G>A p.P361= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs1299021796, COSV61125825; called by muse, mutect2, varscan2
- SH3TC1 | c.252G>C p.L84= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV55285223, COSV99794395; called by muse, mutect2, varscan2
- SLC14A2 | c.156C>G p.L52= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54909825; called by muse, mutect2, varscan2
- SRGAP3 | c.408C>T p.I136= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV64534222; called by muse, mutect2, varscan2
- SUMO3 | c.189G>A p.G63= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60538142; called by muse, mutect2
- SYNE2 | c.15933G>A p.E5311= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59953708; called by muse, mutect2, varscan2
- TNXB | c.11145C>A p.S3715= (on ENST00000647633; = p.S3468= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV64480385; called by muse, mutect2, varscan2
- TUBAL3 | c.366C>T p.I122= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs144348755; called by muse, mutect2, varscan2
- VSIG8 | c.817C>T p.L273= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV63652903; called by muse, mutect2, varscan2
- ZNF445 | c.27C>A p.A9= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV68538994; called by muse, mutect2, varscan2
- ZNF667 | c.1266G>A p.K422= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1568831225, COSV52634392; called by muse, mutect2, varscan2
- C11orf40 | n.344C>G | RNA (SNP) | VAF 12/40 reads (30%) | catalogued as rs141444146, COSV56890754; called by muse, mutect2, varscan2
- MAP4 | c.1999+5038G>A | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as COSV53138474; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86034C>T | Intron (SNP) | VAF 40/128 reads (31%) | catalogued as rs747384089, COSV72277400, COSV72278078; called by mutect2, varscan2
- PLCD1 | c.35-4006G>A | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58161577; called by muse, mutect2
- WASF4P | n.1471G>C | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- XIRP2 | c.*473G>A | 3'UTR (SNP) | VAF 23/77 reads (30%) | catalogued as rs1441795523, COSV54706318; called by muse, mutect2, varscan2
- ZNF688 | c.-584C>T | 5'UTR (SNP) | VAF 15/54 reads (28%) | catalogued as COSV56301024; called by muse, mutect2, varscan2
